Gene-level copy-number profile of tumor specimen C3N-02422-01 (profiled together with C3N-02422-02) from CPTAC case C3N-02422, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 56.3 years (20,562 days).
Specimen C3N-02422-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 01e6d129-3c95-442f-bfa4-12df9c9648cf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02422-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/dfcbb40f-8c17-44b9-82ae-74735179d492

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 3,217; copy number 2: 35,055; copy number 3: 8,196; copy number 4: 10,040; copy number 5: 1,473; copy number 6: 266; copy number 7: 33; copy number 8: 13; copy number 9: 3; copy number 10: 49; copy number 11: 1; copy number 14: 28.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:2,088,718–2,090,617, 1 gene (within-gene range 0–2): AL136360.1.
- chr9:21,966,929–25,089,151, 26 genes (within-gene range 0–1): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3, IZUMO3, AL353811.1, RMRPP5, RN7SKP120.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,852 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:123,065,321–125,823,315, 17 genes, copy number 5: AC062020.1, LINC01826, AC073409.1, ELOAP1, PSMD14P1, AC064859.1, RN7SKP102, AC079154.1, CNTNAP5, MTND5P22, AC019159.2, AC019159.1, RNA5SP102, RNU6-259P, AC097499.2, LINC01889, AC097499.1.
- chr2:129,063,846–132,646,582, 151 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr4:142,023,160–144,343,750, 28 genes, copy number 14: INPP4B, RPL5P13, LSM3P4, AC139720.2, AC139720.1, AC104596.1, AC104596.2, USP38, AC097658.2, Y_RNA, GAB1, MIR3139, AC097658.1, AC097658.3, RPSAP36, AC104685.1, SMARCA5-AS1, SMARCA5, AC139713.1, AC107223.1, GUSBP5, FREM3, AC104090.1, GYPE, AC093890.1, GYPB, AC093890.2, GYPA.
- chr6:41,381,392–44,553,281, 122 genes, copy number 6 (broad region; genes not listed).
- chr6:45,880,827–49,116,115, 40 genes, copy number 5–7: CLIC5, RNU6-754P, AL035701.1, ENPP4, ENPP5, ACTG1P9, RCAN2, AL359633.1, AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1, TNFRSF21, B3GNTL1P2, AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P, PTCHD4, HNRNPA3P4, RBMXP1, FO393412.1, AL022099.1, AL589994.1, AL589994.2.
- chr7:38,239,580–38,340,998, 17 genes, copy number 5: TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr12:16,347,142–16,609,259, 1 gene, copy number 6 (within-gene range 2–6): MGST1.
- chr12:16,420,653–16,610,594, 4 genes, copy number 6 (within-gene range 2–6): AC007528.1, AC007552.1, LMO3, AC007552.2.
- chr12:28,978,584–29,497,686, 11 genes, copy number 6–9: AC024255.1, AC012150.1, FAR2, AC012150.2, AC009318.4, AC009318.1, AC009318.3, AC009318.2, ERGIC2, OVCH1-AS1, OVCH1.
- chr12:62,935,701–63,360,037, 10 genes, copy number 5–10: Y_RNA, RPL14P1, AC078814.2, LDHAL6CP, AC078814.1, RSL24D1P5, AVPR1A, AC135584.1, HNRNPA1P69, AC026116.1.
- chr12:63,844,700–73,846,188, 194 genes, copy number 5–7 (broad region; genes not listed).
- chr12:73,906,940–73,919,337, 1 gene, copy number 5: AC136188.1.
- chr12:79,341,205–80,680,273, 19 genes, copy number 5 (within-gene range 2–5): AC027288.3, MIR1252, AC027288.2, AC027288.1, NOP56P3, PAWR, AC073569.2, PPP1R12A, AC073569.3, AC073569.1, RNA5SP363, PPP1R12A-AS1, SNRPGP20, RPL7P38, RNU7-106P, OTOGL, AC078817.1, RN7SKP261, PTPRQ.
- chr12:110,614,027–112,509,918, 52 genes, copy number 5–6: TCTN1, RN7SL387P, HVCN1, PPP1CC, AC144522.1, AC002375.1, RPL29P25, CCDC63, MYL2, LINC01405, AC002351.1, CUX2, MIR6760, RNA5SP373, PHETA1, LINC02356, HSPA8P14, SH2B3, ATXN2, U7, IFITM3P5, ATXN2-AS, BRAP, PCNPP1, ACAD10, AC002996.1, ALDH2, MIR6761, MAPKAPK5-AS1, MAPKAPK5, RPS2P41, ADAM1A, ADAM1B, TMEM116, SLC25A3P2, AC004024.1, ERP29, AC073575.2, NAA25, MIR3657, AC073575.1, Y_RNA, TRAFD1, Y_RNA, HECTD4, MIR6861, AC004217.1, RN7SKP71, RPL7AP60, AC004217.2, RPL6, PTPN11.
- chr15:19,878,555–19,887,814, 2 genes, copy number 5: AC138701.1, RNU6-978P.
- chr15:56,630,181–56,734,086, 1 gene, copy number 5 (within-gene range 4–5): ZNF280D.
- chr15:56,652,488–57,782,762, 23 genes, copy number 5: AC090517.4, AC090517.2, AC090517.3, AC090517.5, AC090517.1, AC010999.2, AC010999.1, TCF12, HNRNPA3P11, SNORD13D, LINC00926, LINC01413, NDUFB10P1, CGNL1, RNU6-844P, AC025271.3, AC025271.2, AC025271.4, AC025271.1, MYZAP, GCOM1, POLR2M, AC090651.1.
- chr16:991,151–18,379,331, 593 genes, copy number 5–10 (within-gene range 3–10) (broad region; genes not listed).
- chr16:46,469,341–49,399,431, 73 genes, copy number 5 (broad region; genes not listed).
- chr16:57,882,340–68,722,616, 235 genes, copy number 5 (broad region; genes not listed).
- chr16:71,281,389–82,192,790, 258 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,847. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
